Surgical pathology report (de-identified scan), TCGA case TCGA-85-8582, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8582-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

ID	Gross Description
[REDACTED]	Lung tissue 18x16 cm with pinky-gray tumor of 2 cm in its largest diameter.

[page 2 of 4]
Microscopic Description	Diagnosis Details
Keratinizing squamous cell carcinoma, G-1. In the S3 there is an micro abscess. Separate small piece of the bronchus is of normal structure. Eight examined lymph nodes are with signs of antracosis.	Tumor Features: -1, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 3 of 4]
Comments	Formatted Path Report
Separate small piece of the bronchus - more likely it should means margins.	LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 0 x 0 x 2 cm Histologic type: Squamous cell carcinoma, keratinizing Histologic grade: Well differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 0/8 positive for metastasis (Bronchopulmonary 0/8) Lymphatic invasion: Not specified Venous invasion: Absent Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Left- upper

[page 4 of 4]
[REDACTED]	ID	Excision date
[REDACTED]		[REDACTED]

Source: NCI Genomic Data Commons file b556ad90-ecc2-418b-a538-7fe9a823f9a8 (TCGA-85-8582.CCCEA878-6599-41B7-BA07-DBE073CD51B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).